Gene-level copy-number profile of specimen HCM-CSHL-0823-C34-85M from HCMI case HCM-CSHL-0823-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 62.8 years (22,955 days).
Specimen HCM-CSHL-0823-C34-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9fb2d30b-d8fd-4235-aabc-7d134000bafb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0823-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/ea68c2f4-919b-45f9-a251-d8678ef68d0e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,127; copy number 2: 16,419; copy number 3: 22,086; copy number 4: 9,160; copy number 5: 5,964; copy number 6: 812; copy number 7: 614; copy number 8: 164; copy number 9: 367; copy number 10: 84; copy number 11: 76; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,458,870–89,459,437, 1 gene (within-gene range 0–1): AC092120.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,306 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,645,278, 6 genes, copy number 7: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35.
- chr3:164,001,606–170,418,615, 84 genes, copy number 10 (broad region; genes not listed).
- chr3:187,368,385–198,123,232, 229 genes, copy number 7–8 (broad region; genes not listed).
- chr6:26,686,241–26,687,964, 1 gene, copy number 12: AL513548.1.
- chr6:41,666,906–66,094,909, 355 genes, copy number 7–11 (broad region; genes not listed).
- chr7:76,397,518–96,709,891, 254 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr17:44,170,447–44,268,141, 10 genes, copy number 7: ASB16, ASB16-AS1, TMUB2, ATXN7L3, AC004596.1, UBTF, MIR6782, AC003102.1, SHC1P2, SLC4A1.
- chr18:45,034–15,330,282, 367 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,867. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
